Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A90R, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A90R-01A (Primary Tumor).

Collect date: (MM/DD/YYYY)

ICD-O-3
Mixed germ cell tumor
Site @ Testis NOS
968513
C62.9
9/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

Product of radical left orchiectomy:

Malignant mixed germ cell tumor with the following characteristics:

- Histological types:
- o Mature teratoma: 10%.
- o Choriocarcinoma: 5%.
- o Classic seminoma: 85%.
- Presence of extensive tumoral necrotic areas.
- The tumor measures 10.0 cm in the longest axis.
- Tumoral infiltration of tunica albuginea present, without transposing it.
- Absence of tumoral infiltration of tunica vaginalis and spermatic cord.
- Angiolymphatic invasion not observed.
- Surgical margins uninvolved by neoplasia.

Site:	W. 11/5/13	Yes	No
Justification for Primary Nucleus			

Source: NCI Genomic Data Commons file 53a5813d-ca24-44a4-9ed0-41af39604596 (TCGA-YU-A90R-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).